MMRF case MMRF_2366 — Multiple Myeloma CoMMpass Study (MMRF-COMMPASS)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Plasma Cell Tumors; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): first treatment.
https://portal.gdc.cancer.gov/cases/dd0b8ccc-0032-42bb-a796-3e023b99582b

Demographics
Sex at birth: female; Race: white; Ethnicity: not hispanic or latino; Age at index: 75 years; Vital status: Alive.

Diagnoses (1)
1. Multiple myeloma: ICD-O-3 morphology code: 9732/3; Tissue or organ of origin: Bone marrow; Site of resection or biopsy: Bone marrow; Age at diagnosis: 75.7 years (27,633 days); ISS stage: I; Days to last known disease status: 710 days (1.9 years); Days to last follow up: 710 days (1.9 years).
   Treatment given: Therapeutic agents: Bortezomib + Cyclophosphamide + Dexamethasone; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 42 days.
   Treatment given: Therapeutic agents: Bortezomib + Dexamethasone; Regimen or line of therapy: Second line of therapy; Days to treatment start: 80 days; Days to treatment end: 261 days.
   Treatment given: Therapeutic agents: Lenalidomide; Regimen or line of therapy: Second line of therapy; Days to treatment start: 80 days; Days to treatment end: 164 days.
   Treatment given: Therapeutic agents: Bendamustine + Bortezomib + Dexamethasone; Regimen or line of therapy: Second line of therapy; Days to treatment start: 261 days; Days to treatment end: 287 days.
   Treatment given: Therapeutic agents: Carfilzomib; Regimen or line of therapy: Fourth line of therapy; Days to treatment start: 324 days.
   Treatment given: Therapeutic agents: Dexamethasone; Regimen or line of therapy: Fourth line of therapy; Days to treatment start: 324 days; Days to treatment end: 387 days (1.1 years).
   Treatment given: Therapeutic agents: Dexamethasone; Regimen or line of therapy: Fourth line of therapy; Days to treatment start: 387 days (1.1 years).

Molecular and laboratory tests (laboratory values one line per visit day; values rounded to 3 significant figures where GDC's unit conversion carried more)
- Day -19: M Protein 2.15 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 97.1 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.045 mg/dL; Immunoglobulin G 27.7 g/L; Immunoglobulin A 0.16 g/L; Immunoglobulin M 0.17 g/L; Beta 2 Microglobulin 1.63 µg/mL; Lactate Dehydrogenase 2.5 µkat/L; Hemoglobin 8 mmol/L; Leukocytes 5.6 ×10⁹/L; Absolute Neutrophil 3.6 ×10⁹/L; Platelets 187 ×10⁹/L; Creatinine 36.2 µmol/L; Blood Urea Nitrogen 4.28 mmol/L; Calcium 2.25 mmol/L; Albumin 43 g/L; Total Protein 8.8 g/dL; Glucose 4.57 mmol/L; C-Reactive Protein 0.09 mg/dL.
- Day 80 (ECOG 1): M Protein 1.9 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 13.5 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.047 mg/dL; Immunoglobulin G 22.9 g/L; Immunoglobulin A 0.08 g/L; Immunoglobulin M 0.08 g/L; Lactate Dehydrogenase 3.17 µkat/L; Hemoglobin 7.63 mmol/L; Leukocytes 6.2 ×10⁹/L; Absolute Neutrophil 4.8 ×10⁹/L; Platelets 197 ×10⁹/L; Creatinine 65.4 µmol/L; Blood Urea Nitrogen 7.5 mmol/L; Calcium 2.4 mmol/L; Albumin 48 g/L; Total Protein 8.8 g/dL; Glucose 5.5 mmol/L.
- Day 170 (ECOG 1): Serum Free Immunoglobulin Light Chain, Kappa 23 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.773 mg/dL; Immunoglobulin G 13.6 g/L; Immunoglobulin A 0.17 g/L; Immunoglobulin M 0.1 g/L; Beta 2 Microglobulin 2.9 µg/mL; Lactate Dehydrogenase 2.52 µkat/L; Hemoglobin 7.01 mmol/L; Leukocytes 7 ×10⁹/L; Absolute Neutrophil 4.6 ×10⁹/L; Platelets 169 ×10⁹/L; Creatinine 76 µmol/L; Blood Urea Nitrogen 7.85 mmol/L; Calcium 2.23 mmol/L; Albumin 42 g/L; Total Protein 7.1 g/dL; Glucose 7.32 mmol/L.
- Day 261 (ECOG 1): M Protein 0.78 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 19.5 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.147 mg/dL; Immunoglobulin G 11.7 g/L; Immunoglobulin A 0.11 g/L; Immunoglobulin M 0.12 g/L; Lactate Dehydrogenase 2.53 µkat/L; Hemoglobin 6.76 mmol/L; Leukocytes 12.5 ×10⁹/L; Absolute Neutrophil 11.2 ×10⁹/L; Platelets 206 ×10⁹/L; Creatinine 93.7 µmol/L; Blood Urea Nitrogen 10 mmol/L; Calcium 2.4 mmol/L; Albumin 44 g/L; Total Protein 7.2 g/dL; Glucose 5.39 mmol/L.
- Day 352 (ECOG 1): M Protein 0.7 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 21.5 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.498 mg/dL; Immunoglobulin G 11.8 g/L; Immunoglobulin A 0.17 g/L; Immunoglobulin M 0.22 g/L; Beta 2 Microglobulin 2.36 µg/mL; Lactate Dehydrogenase 2.73 µkat/L; Hemoglobin 7.01 mmol/L; Leukocytes 5.6 ×10⁹/L; Absolute Neutrophil 3.9 ×10⁹/L; Platelets 168 ×10⁹/L; Creatinine 52.2 µmol/L; Blood Urea Nitrogen 6.43 mmol/L; Calcium 2.3 mmol/L; Albumin 44 g/L; Total Protein 7.2 g/dL; Glucose 4.57 mmol/L.
- Day 408 (ECOG 1): M Protein 0.46 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 15.5 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.734 mg/dL; Immunoglobulin G 11.1 g/L; Immunoglobulin A 0.26 g/L; Immunoglobulin M 0.24 g/L; Lactate Dehydrogenase 2.93 µkat/L; Hemoglobin 7.32 mmol/L; Leukocytes 6.8 ×10⁹/L; Absolute Neutrophil 5.3 ×10⁹/L; Platelets 215 ×10⁹/L; Creatinine 58.3 µmol/L; Blood Urea Nitrogen 5.36 mmol/L; Calcium 2.43 mmol/L; Albumin 43 g/L; Total Protein 6.9 g/dL; Glucose 5.17 mmol/L.
- Day 520 (ECOG 2): M Protein 0.26 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 2.56 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.723 mg/dL; Immunoglobulin G 6.75 g/L; Immunoglobulin A 0.34 g/L; Immunoglobulin M 0.11 g/L; Lactate Dehydrogenase 2.9 µkat/L; Hemoglobin 6.7 mmol/L; Leukocytes 5.3 ×10⁹/L; Absolute Neutrophil 3.9 ×10⁹/L; Platelets 126 ×10⁹/L; Creatinine 65.4 µmol/L; Blood Urea Nitrogen 6.07 mmol/L; Calcium 2.3 mmol/L; Albumin 39 g/L; Total Protein 5.9 g/dL; Glucose 5.89 mmol/L.
- Day 618 (ECOG 1): M Protein 0.16 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 4.55 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.02 mg/dL; Immunoglobulin G 11.7 g/L; Immunoglobulin A 1.09 g/L; Immunoglobulin M 0.67 g/L; Beta 2 Microglobulin 1.67 µg/mL; Lactate Dehydrogenase 2.1 µkat/L; Hemoglobin 7.63 mmol/L; Leukocytes 7.2 ×10⁹/L; Absolute Neutrophil 5.5 ×10⁹/L; Platelets 278 ×10⁹/L; Creatinine 56.6 µmol/L; Blood Urea Nitrogen 6.07 mmol/L; Calcium 2.4 mmol/L; Albumin 41 g/L; Total Protein 6.1 g/dL; Glucose 5.01 mmol/L.
- Day 710 (ECOG 1): M Protein 0.15 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 4.83 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.05 mg/dL; Immunoglobulin G 12.5 g/L; Immunoglobulin A 0.95 g/L; Immunoglobulin M 0.25 g/L; Lactate Dehydrogenase 3.4 µkat/L; Hemoglobin 7.75 mmol/L; Leukocytes 6 ×10⁹/L; Absolute Neutrophil 3.7 ×10⁹/L; Platelets 215 ×10⁹/L; Creatinine 81.3 µmol/L; Blood Urea Nitrogen 8.57 mmol/L; Calcium 2.43 mmol/L; Albumin 41 g/L; Total Protein 7.1 g/dL; Glucose 5.12 mmol/L.

Other clinical attributes
- Day -19: Weight: 91 kg; Height: 162 cm.

Biospecimens (2 samples)
- Sample MMRF_2366_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS; Days to sample procurement: -19 days.
- Sample MMRF_2366_1_PB_Whole: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS; Days to sample procurement: -19 days.
